Surgical pathology report (de-identified scan), TCGA case TCGA-71-8520, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ILSBio, specimen TCGA-71-8520-01A (Primary Tumor).

[page 1 of 5]
Clinical Information

HISTORY OF PRESENT ILLNESS

Chief Complaints: persistent cough ; Hemoptysis

Symptoms: Shortness of breath ; weight loss

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day
☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal ☐ Peri-Menopausal ☒ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____	CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____	CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____	CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____	PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____	Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:					

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray	left lung tumor	
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T 2 N 0 M 0 Stage: I B	

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of the upper lobe of the lung			
Primary Tumor			
Organ	Detailed Location	Size	
left lung tumor	upper lobe	3 x 3 x cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T 2 N 0 M 0 Stage: I B			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
left Lung Tumor	3 x 3 x cm	upper lobe	7 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 0 M 0		Stage: IB	
Notes:			

[page 5 of 5]
1. *Histological pattern:*

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse				Streaming			
Mosaic			✓	Storiform			
Necrosis		✓		Fibrosis			
Lymphocytic Infiltration		✓		Palisading			
Vascular Invasion			✓	Cystic Degeneration			
Clusterized		✓		Bleeding			
Alveolar Formation			✓	Myxoid Change			
Indian File			✓	Psammoma/Calcification			

2. *Cellular features:*

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	✓		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	✓		Fibroblast			Small Cell		
Keratin			Secretion	✓		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	✓		Lipoblast			Inflam. Cell		
Pearl			Gland formation	✓		Myoblast			Plasma Cell		

Otherwise Specified:

D₁ 70% D₂ 70% D₃ 60% D₄ 70%

recovered

2%

2. *Cellular Differentiation:*

Well	Moderately	Poor
	✓	

3. *Nuclear Atypia:*

Nuclear Appearance		0	I	II	III
Aniso Nucleosis			✓		
Hyperchromatism			✓		
Nucleolar Prominent			✓		
Multinucleated Giant Cell			✓		
Mitotic Activity			✓		
Nuclear Grade			✓		

Source: NCI Genomic Data Commons file 95d3aa84-5bda-4e7f-936e-d40ae043cffa (TCGA-71-8520.3EAD80D6-5B6E-49FF-87A2-AED7ABB8E2E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).